Somatic mutation profile of tumor specimen ER-ADIN-TTM1-A (aliquot ER-ADIN-TTM1-A-1-0-D-A515-35) from EXCEPTIONAL_RESPONDERS case ER-ADIN, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IVB; Age at diagnosis: 54.1 years (19,760 days).
Specimen ER-ADIN-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cddaae4-d466-4546-a749-9f1a72f620cb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADIN-NT1-A (Solid Tissue Normal), aliquot ER-ADIN-NT1-A-1-0-D-A515-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94037ae6-2dc7-4bc2-8019-f4b6c64bfae6

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 190/500 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PIK3R1 | c.1678G>T p.D560Y (on ENST00000521381 / NM_181523.3; = p.D290Y on NM_181504.4) | Missense Mutation (SNP) | VAF 85/433 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1057519839, COSV57123942, COSV57127598, COSV57130158; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 329/562 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3413A>G p.H1138R (on ENST00000357008 / NM_001363606.2; = p.H1151R on NM_001273.5) | Missense Mutation (SNP) | VAF 99/620 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as COSV58903706, COSV58909861; called by muse, mutect2, varscan2
- ARID1A | c.2460del p.N820Kfs*13 | Frame Shift Del (DEL) | VAF 98/544 reads (18%) | called by mutect2, pindel, varscan2
- TSC2 | c.5008dup p.H1670Pfs*36 | Frame Shift Ins (INS) | VAF 108/474 reads (23%) | called by mutect2, pindel, varscan2
